Somatic mutation profile of tumor specimen TCGA-DU-5870-01A (aliquot TCGA-DU-5870-01A-11D-1705-08) from TCGA case TCGA-DU-5870, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 34.9 years (12,764 days).
Specimen TCGA-DU-5870-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a27df82b-fe92-48de-8c9a-0b3d276fb453.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-5870-10A (Blood Derived Normal), aliquot TCGA-DU-5870-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d13eab6-079d-4a2f-bdd5-c8ad1b6c3fbb

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 9, Silent 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568504941, COSV50547203; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 29/79 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 32/99 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRA3 | c.2912A>G p.N971S | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs372378305; called by muse, mutect2, varscan2
- FOXK1 | c.1183C>G p.R395G | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV61067837; called by muse, mutect2, varscan2
- RAB3B | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV63228411; called by muse, mutect2, varscan2
- SPZ1 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.149); catalogued as rs780303532, COSV99698245; called by muse, varscan2
- TNR | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54904662; called by muse, mutect2, varscan2
- TRMT10A | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV56745820; called by muse, mutect2, varscan2
- TMEM132B | c.61_62del p.G23Dfs*4 | Frame Shift Del (DEL) | VAF 29/106 reads (27%) | called by pindel, varscan2
- ERCC6L2 | c.4395A>G p.S1465= | Silent (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- IRX2 | c.309C>T p.Y103= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs748509438, COSV57410966, COSV57412886; called by muse, mutect2, varscan2
- NLRP4 | c.1161C>T p.G387= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV56720116; called by muse, mutect2, varscan2
- PCDHA11 | c.1290T>C p.G430= | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as rs1554164195, COSV56533202; called by muse, mutect2, varscan2
- THBS1 | c.1998G>A p.L666= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV52954624; called by muse, mutect2, varscan2
